CPTAC case C3N-00305 — Kidney — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e897318d-6d4d-4bcb-8a47-332a2070aab7

Demographics
Sex at birth: female; Race: white; Year of birth: 1956; Vital status: Alive; Country of birth: Poland.

Diagnoses (1)
1. Renal cell carcinoma, NOS: ICD-O-3 morphology code: 8312/3; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Age at diagnosis: 60.1 years (21,957 days); Year of diagnosis: 2016; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC pathologic T: T1a; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Tumor grade: G1; Residual disease: RX; Last known disease status: Tumor free; Days to last known disease status: 1,913 days (5.2 years); Progression or recurrence: no; Days to last follow up: 1,913 days (5.2 years); Tumor focality: Multifocal.
   Pathology details: Greatest tumor dimension: 1 cm (a second GDC size field records 2.2 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 0; Margin status: Uninvolved; Sarcomatoid present: No.

Follow-up (6 entries)
- Days to follow up: 455 days (1.2 years); Disease response: Tumor Free.
- Days to follow up: 765 days (2.1 years); Disease response: Tumor Free.
- Days to follow up: 1,203 days (3.3 years); Disease response: With Tumor.
- Days to follow up: 1,397 days (3.8 years); Disease response: Tumor Free.
- Days to follow up: 1,877 days (5.1 years); Disease response: Complete Response; Progression or recurrence: Yes; Days to recurrence: 199 days.
- Days to follow up: 1,913 days (5.2 years); Disease response: Tumor Free.

Other clinical attributes
- Weight: 52 kg; Height: 164 cm; BMI: 19.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 38; Cigarettes per day: 20; Tobacco smoking onset year: 1978; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 44.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-00305-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Freezing method: LN2; Initial weight: 397 mg.
- Sample C3N-00305-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -7 days; Initial weight: 430 mg; Time between excision and freezing: 5 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-00305-22: Section location: Middle; Percent tumor nuclei: 90; Percent necrosis: 5.
- Sample C3N-00305-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -7 days; Method of sample procurement: Blood Draw.
